Somatic mutation profile of tumor specimen ALCH-B5FH-TTP1-A (aliquot ALCH-B5FH-TTP1-A-1-0-D-A85H-36) from ALCHEMIST case ALCH-B5FH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 58.7 years (21,435 days).
Specimen ALCH-B5FH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7776cb3f-12e9-45ff-81ab-0aee942cbd7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B5FH-NB1-A (Blood Derived Normal), aliquot ALCH-B5FH-NB1-A-1-0-D-A85H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4f4e2fd-6f88-4172-9e34-8ac83ab9b52d

The open-access MAF lists 273 somatic variants for this specimen: 175 protein-altering or splice-affecting, 63 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 63, Nonsense Mutation 15, Intron 12, 3'UTR 8, 5'UTR 7, Splice Region 5, RNA 4, Splice Site 4, Frame Shift Del 3, 3'Flank 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 66/316 reads (21%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC013489.1 | c.1530C>G p.I510M | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV51554617; called by muse, mutect2
- ADD1 | c.2084C>G p.S695* | Nonsense Mutation (SNP) | VAF 8/149 reads (5%) | catalogued as COSV99296099; called by muse, mutect2
- ADGRV1 | c.11893G>A p.E3965K | Missense Mutation (SNP) | VAF 20/418 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as rs867539453; called by muse, mutect2
- ANKRD11 | c.3469G>C p.E1157Q | Missense Mutation (SNP) | VAF 27/416 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as COSV56354852, COSV56358780; called by muse, mutect2
- ATM | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 57/411 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs55633650, COSV53753248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BUB1B | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV55010448; called by muse, mutect2
- CAMK1D | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV66617145; called by muse, mutect2, varscan2
- CDKN2A | c.212A>C p.N71T | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs559848002, CM112063, CM940228, CM983987, COSV58705792; called by muse, mutect2, varscan2
- CEP76 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as COSV100042541; called by muse, mutect2
- CFH | c.1523C>G p.S508C | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV66412387; called by muse, mutect2
- CHRDL2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as COSV99733608; called by muse, mutect2
- CLDN17 | c.583T>A p.Y195N | Missense Mutation (SNP) | VAF 14/485 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV54523526; called by muse, mutect2
- CPNE4 | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV70189588; called by muse, mutect2
- CRNN | c.699G>C p.Q233H | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs749701159; called by muse, mutect2, varscan2
- DCHS1 | c.4726G>A p.E1576K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100201611; called by muse, mutect2, varscan2
- DCTN2 | c.109G>A p.E37K (on ENST00000548249 / NM_001261413.2; = p.E42K on NM_006400.4) | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1275627780, COSV71553335; called by muse, mutect2
- DISP3 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.054); catalogued as rs1160140767; called by muse, mutect2
- DNAJA3 | c.603C>G p.F201L | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs781398518, COSV52164159, COSV99277137; called by muse, mutect2
- EDC3 | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 34/447 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59339839; called by muse, mutect2
- FAT1 | c.2113G>T p.D705Y | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs200902471; called by muse, mutect2
- FGD4 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 19/500 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56786987; called by muse, mutect2
- FOXD1 | c.1246G>C p.V416L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs1246857805; called by muse, mutect2
- FSTL4 | c.215G>C p.R72P | Missense Mutation (SNP) | VAF 19/279 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.578); catalogued as COSV54768673; called by muse, mutect2
- FZD9 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60669737; called by muse, mutect2, varscan2
- GABRB3 | c.1090C>G p.H364D | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54668041; called by muse, mutect2
- GOLGA7 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs748969594; called by muse, mutect2
- GRIN2D | c.1611C>G p.I537M | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); catalogued as rs1305011831; called by muse, mutect2
- GSTK1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs1029453280, COSV64424186; called by muse, mutect2
- HMCN2 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs565938462; called by muse, mutect2
- IL12RB2 | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as rs1425568068, COSV52019881; called by muse, mutect2
- IQCJ-SCHIP1 | c.1113G>C p.Q371H (on ENST00000485419 / NM_001197113.1; = p.Q295H on NM_014575.3) | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100539360, COSV61850139; called by muse, mutect2
- KDM2B | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100997662; called by muse, mutect2
- LMO7 | c.2152G>C p.E718Q (on ENST00000357063; = p.E399Q on NM_005358.5) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58552011; called by muse, mutect2
- LPCAT4 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs144011888; called by muse, mutect2
- LRP1B | c.7094C>G p.P2365R | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67238817, COSV67251298; called by muse, mutect2
- LSM3 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1419546305; called by muse, mutect2
- MAFG | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as rs754838894; called by muse, mutect2, varscan2
- MFAP4 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.133); catalogued as rs1406206767, COSV55190767; called by muse, mutect2, varscan2
- MLXIPL | c.416A>G p.K139R | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1554598777; called by muse, mutect2
- MPDZ | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59941584; called by muse, mutect2
- MUC4 | c.10177C>A p.L3393I | Missense Mutation (SNP) | VAF 41/558 reads (7%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.374); catalogued as rs1232751719; called by muse, mutect2
- MYH7 | c.2628G>C p.K876N | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62516642; called by muse, mutect2
- NFKBIZ | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs769960902, COSV58199954, COSV58200788; called by muse, mutect2
- NLRP13 | c.1544C>G p.S515C | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61624559; called by muse, mutect2
- NPHP3 | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 46/487 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.159); catalogued as CM139048; called by muse, mutect2
- NUBP1 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV51593583; called by muse, mutect2, varscan2
- OR51M1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV60784346; called by muse, mutect2, varscan2
- PASK | c.2641G>A p.G881R | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1433216112, COSV99299307; called by muse, mutect2, varscan2
- PATL2 | c.866C>G p.T289S | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs533258380; called by muse, mutect2, varscan2
- PDZRN4 | c.2227G>A p.E743K (on ENST00000402685 / NM_001164595.2; = p.E485K on NM_013377.4) | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54192285, COSV54198313; called by muse, mutect2
- PGM5 | c.1341G>A p.M447I | Missense Mutation (SNP) | VAF 12/303 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV67167437; called by muse, mutect2
- PPP1R37 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs1400094739, COSV55526484; called by muse, mutect2
- PRM1 | c.78G>C p.R26S | Missense Mutation (SNP) | VAF 65/611 reads (11%) | PolyPhen probably damaging (0.998); catalogued as COSV54113374; called by muse, mutect2, varscan2
- PRPF40A | c.2494G>T p.D832Y | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68356618; called by muse, mutect2
- PRRT2 | c.976_978del p.L326del | In Frame Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs775617472; called by mutect2, pindel, varscan2
- PSME4 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV101122247; called by muse, mutect2
- RABGGTA | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs1350430713; called by muse, mutect2, varscan2
- RAD51C | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 18/460 reads (4%) | catalogued as COSV61677447; called by muse, mutect2
- SCN7A | c.3296C>T p.S1099F | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1390364556; called by muse, mutect2
- SEMA3E | c.999T>C p.S333= | Splice Region (SNP) | VAF 34/329 reads (10%) | catalogued as rs1258125234; called by muse, mutect2, varscan2
- SERPINA5 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.147); catalogued as rs1289731471, COSV100291580; called by muse, mutect2
- SERPINI1 | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 14/436 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1303938607; called by muse, mutect2
- SGO2 | c.134-1G>A p.X45_splice | Splice Site (SNP) | VAF 13/115 reads (11%) | catalogued as COSV104416850; called by muse, mutect2, varscan2
- SLC26A1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387907488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SORL1 | c.1640G>C p.G547A | Missense Mutation (SNP) | VAF 10/341 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52757552; called by muse, mutect2
- SYNE2 | c.4447G>C p.E1483Q | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59956369; called by muse, mutect2
- UTRN | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV62348974; called by muse, mutect2, varscan2
- VEGFB | c.375-3C>G | Splice Region (SNP) | VAF 16/87 reads (18%) | catalogued as rs1245205035; called by muse, mutect2, varscan2
- VIT | c.1609G>A p.V537M (on ENST00000389975 / NM_001177969.1; = p.V552M on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs774353511; called by muse, mutect2, varscan2
- ZNF229 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs769889297; called by muse, mutect2, varscan2
- ZNF630 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.451); catalogued as rs782804164, COSV99332512; called by muse, mutect2
- ZP2 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs745316365; called by muse, mutect2, varscan2
- AASDH | c.2531G>A p.G844E | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCB5 | c.3229G>C p.D1077H (on ENST00000404938 / NM_001163941.2; = p.D632H on NM_178559.6) | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC9 | c.4228G>A p.E1410K | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- ANGPT1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 26/692 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD31 | c.5339C>G p.S1780C | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- APEH | c.2149G>A p.D717N | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2
- APLNR | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.07); called by muse, mutect2
- BIN3 | c.460G>C p.V154L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2
- BTBD7 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- C17orf78 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, varscan2
- CALM2 | c.4-8C>G | Splice Region (SNP) | VAF 12/359 reads (3%) | called by muse, mutect2
- CCDC105 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- CCDC141 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK13 | c.2627C>T p.T876I | Missense Mutation (SNP) | VAF 11/293 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CELF4 | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 53/359 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CEP250 | c.5950C>G p.L1984V | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHAF1A | c.357G>C p.L119F | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CIART | c.1079G>C p.R360T | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); called by muse, mutect2
- CNST | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- COL11A1 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 46/722 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL17A1 | c.2737C>T p.P913S | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL4A3 | c.3827C>G p.P1276R | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- CSDE1 | c.200-1G>C p.X67_splice | Splice Site (SNP) | VAF 11/183 reads (6%) | called by muse, mutect2
- DCAF8L1 | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 8/211 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.236); called by muse, mutect2
- DEF6 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 28/412 reads (7%) | called by muse, mutect2
- DIMT1 | c.810C>G p.F270L | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DKK1 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- DNAH8 | c.13362G>C p.K4454N | Missense Mutation (SNP) | VAF 23/457 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DNAJC5B | c.393C>G p.C131W | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2
- DPYS | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EFHB | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF3J | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EIF4A1 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 9/258 reads (3%) | called by muse, mutect2
- EIF5A2 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 20/369 reads (5%) | called by muse, mutect2
- ELOVL5 | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2
- EP300 | c.2747C>G p.S916* | Nonsense Mutation (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2, varscan2
- EP300 | c.3073G>C p.E1025Q | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); called by muse, mutect2
- EPB41L4B | c.2673G>A p.M891I | Missense Mutation (SNP) | VAF 17/265 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- F5 | c.4880C>G p.T1627S | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.054); called by muse, mutect2
- FAM114A2 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 23/309 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM71E2 | c.1162A>G p.M388V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO46 | c.1489A>T p.K497* | Nonsense Mutation (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- GAB1 | c.367+1G>A p.X123_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- GPSM2 | c.1896C>A p.F632L | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); called by muse, mutect2
- GRID2 | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2
- H2BC6 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 58/574 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); called by muse, mutect2
- HECTD2 | c.1173G>C p.Q391H | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- HOXD10 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 11/325 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- IGHV3-49 | c.267C>A p.F89L | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); called by muse, mutect2
- IMPA1 | c.550del p.C184Afs*52 | Frame Shift Del (DEL) | VAF 18/178 reads (10%) | called by mutect2, pindel
- IQCG | c.253C>G p.Q85E | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.152); called by muse, mutect2
- IRAK4 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 12/436 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ITGA2B | c.879G>C p.W293C | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- KRT79 | c.265G>C p.G89R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- LCOR | c.3988G>A p.E1330K | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- LRIG2 | c.804-1G>C p.X268_splice | Splice Site (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- MAGEB3 | c.690G>C p.M230I | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); called by muse, mutect2
- MAPKAPK3 | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MARK2 | c.475-3C>G | Splice Region (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
- MAST4 | c.6049T>G p.S2017A (on ENST00000403625 / NM_001164664.2; = p.S1828A on NM_015183.3) | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MIB1 | c.126C>G p.F42L | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- MTCH1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- MYO5B | c.1863G>T p.M621I | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- NELFCD | c.1800A>T p.*600Yext*124 (on ENST00000602795; = p.*582Yext*124 on NM_198976.4) | Nonstop Mutation (SNP) | VAF 28/290 reads (10%) | called by muse, mutect2
- OAS3 | c.2644G>C p.D882H | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); called by muse, mutect2
- OR52A5 | c.779_781del p.F260del | In Frame Del (DEL) | VAF 37/211 reads (18%) | called by pindel, varscan2
- ORM1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.137); called by muse, mutect2
- PAX5 | c.740C>G p.S247* | Nonsense Mutation (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- PCDHB14 | c.1485C>A p.D495E | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); called by muse, mutect2
- PCNP | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 40/472 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.134); called by muse, mutect2
- PHF19 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- PIGQ | c.1419C>G p.L473= | Splice Region (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2
- PIK3C2B | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLXNA1 | c.5247C>G p.F1749L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM12 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); called by muse, mutect2
- RNF144B | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 8/227 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- RYR1 | c.10196C>G p.S3399C | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2
- SCARF2 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- SCLT1 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- SEC24B | c.2284_2287del p.L762Mfs*7 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | called by mutect2, pindel, varscan2
- SEC24D | c.2312C>G p.S771C | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- SEC31B | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH3PXD2B | c.2312C>T p.S771L | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SKOR1 | c.2276G>C p.R759P | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLC17A4 | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2
- TASOR2 | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TBC1D10B | c.1492del p.L498Cfs*23 | Frame Shift Del (DEL) | VAF 15/157 reads (10%) | called by mutect2, pindel
- TCEANC2 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 19/199 reads (10%) | called by muse, mutect2
- TNFRSF14 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- TOPORS | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); called by muse, mutect2
- TSPAN32 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); called by muse, mutect2
- TUBB | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- USH2A | c.3772G>C p.E1258Q | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); called by muse, mutect2
- USP31 | c.1694G>C p.R565T | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2
- WDR47 | c.1298G>C p.R433T (on ENST00000369962 / NM_001142551.2; = p.R434T on NM_014969.5) | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2
- WDR48 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- YME1L1 | c.1321G>A p.D441N (on ENST00000326799 / NM_139312.3; = p.D384N on NM_014263.4) | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZBTB8A | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZCCHC7 | c.1298C>G p.S433* | Nonsense Mutation (SNP) | VAF 15/375 reads (4%) | called by muse, mutect2
- ZNF182 | c.758G>A p.W253* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- ZNF608 | c.2189C>G p.S730C | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- ZZZ3 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 42/283 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4686G>C p.V1562= | Silent (SNP) | VAF 24/360 reads (7%) | called by muse, mutect2
- ANGPTL6 | c.141C>G p.P47= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- ANKRD11 | c.3582G>A p.G1194= | Silent (SNP) | VAF 50/648 reads (8%) | catalogued as rs1406734396; called by muse, mutect2
- APC | c.48G>A p.L16= | Silent (SNP) | VAF 46/539 reads (9%) | called by muse, mutect2
- CCDC198 | c.837G>A p.V279= | Silent (SNP) | VAF 40/436 reads (9%) | catalogued as rs371332687; called by muse, mutect2
- CDHR5 | c.2019G>A p.L673= (on ENST00000358353 / NM_001171968.2; = p.L679= on NM_021924.5) | Silent (SNP) | VAF 32/284 reads (11%) | catalogued as rs1004459958; called by muse, mutect2, varscan2
- CEBPB | c.633C>G p.L211= | Silent (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- CELF5 | c.1338G>A p.V446= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- CLPB | c.1647G>A p.L549= | Silent (SNP) | VAF 17/225 reads (8%) | catalogued as rs755229925; called by muse, mutect2
- CPA5 | c.1194C>A p.L398= | Silent (SNP) | VAF 19/246 reads (8%) | called by muse, mutect2
- CTNNA3 | c.702C>T p.L234= | Silent (SNP) | VAF 10/276 reads (4%) | called by muse, mutect2
- CYC1 | c.699C>T p.F233= | Silent (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2
- DNMT3B | c.2220C>G p.P740= | Silent (SNP) | VAF 34/462 reads (7%) | called by muse, mutect2
- ERG | c.993C>T p.S331= (on ENST00000398919 / NM_001243428.1; = p.S307= on NM_004449.4) | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- FGF6 | c.549G>A p.L183= | Silent (SNP) | VAF 14/420 reads (3%) | called by muse, mutect2
- FLNA | c.7212C>T p.V2404= (on ENST00000369850 / NM_001110556.2; = p.V2396= on NM_001456.3) | Silent (SNP) | VAF 22/254 reads (9%) | called by muse, mutect2
- GLYAT | c.444G>A p.L148= | Silent (SNP) | VAF 59/317 reads (19%) | catalogued as COSV53539494; called by muse, mutect2, varscan2
- GPSM2 | c.1350G>A p.L450= | Silent (SNP) | VAF 37/274 reads (14%) | catalogued as rs963843637, COSV99915498; called by muse, mutect2, varscan2
- HARS2 | c.48C>T p.L16= | Silent (SNP) | VAF 34/509 reads (7%) | catalogued as rs1457901727; called by muse, mutect2
- HSPG2 | c.9372G>A p.V3124= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as rs1477758969; called by muse, mutect2
- IRS2 | c.771C>T p.I257= | Silent (SNP) | VAF 24/209 reads (11%) | called by muse, mutect2, varscan2
- LGALS12 | c.345C>G p.L115= | Silent (SNP) | VAF 26/216 reads (12%) | called by muse, mutect2, varscan2
- LRP1 | c.5223G>A p.Q1741= | Silent (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- LRRC58 | c.249C>G p.L83= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as rs758966720; called by muse, mutect2, varscan2
- LRRC8D | c.1632G>A p.V544= | Silent (SNP) | VAF 11/159 reads (7%) | called by muse, mutect2
- MACROD1 | c.177G>A p.A59= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as rs1367113048; called by muse, mutect2, varscan2
- MAGI2 | c.2880G>A p.G960= | Silent (SNP) | VAF 20/178 reads (11%) | catalogued as COSV62635904; called by muse, mutect2, varscan2
- MISP | c.1821C>T p.F607= | Silent (SNP) | VAF 15/178 reads (8%) | called by muse, mutect2
- MRPS26 | c.288G>A p.L96= | Silent (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- MUC16 | c.2427C>G p.L809= | Silent (SNP) | VAF 10/187 reads (5%) | called by muse, mutect2
- MUC17 | c.9864C>G p.V3288= | Silent (SNP) | VAF 9/173 reads (5%) | called by muse, mutect2
- MYO19 | c.1425C>G p.L475= | Silent (SNP) | VAF 19/401 reads (5%) | called by muse, mutect2
- OPRL1 | c.711C>T p.L237= | Silent (SNP) | VAF 9/257 reads (4%) | called by muse, mutect2
- OTOGL | c.957C>T p.F319= (on ENST00000547103; = p.F310= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- PCDHA2 | c.1398G>A p.E466= | Silent (SNP) | VAF 28/434 reads (6%) | called by muse, mutect2
- PEX1 | c.1410A>G p.L470= | Silent (SNP) | VAF 12/356 reads (3%) | called by muse, mutect2
- PHC3 | c.1512G>A p.Q504= (on ENST00000494943 / NM_001308116.2; = p.Q516= on NM_024947.4) | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2, varscan2
- PNMA3 | c.199C>T p.L67= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- PTPN13 | c.1548C>T p.I516= | Silent (SNP) | VAF 36/409 reads (9%) | called by muse, mutect2
- RAB26 | c.279C>T p.F93= | Silent (SNP) | VAF 26/175 reads (15%) | called by muse, mutect2, varscan2
- RALYL | c.261C>T p.I87= | Silent (SNP) | VAF 22/438 reads (5%) | called by muse, mutect2
- RASGRP3 | c.1557C>T p.I519= (on ENST00000402538 / NM_001349975.2; = p.I518= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2, varscan2
- RBBP8NL | c.1785G>A p.T595= | Silent (SNP) | VAF 44/240 reads (18%) | catalogued as rs540423937, COSV53351141; called by muse, mutect2, varscan2
- RHOT1 | c.1150C>T p.L384= | Silent (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- RNF139 | c.828C>T p.L276= | Silent (SNP) | VAF 22/354 reads (6%) | called by muse, mutect2
- RPUSD4 | c.375C>G p.L125= | Silent (SNP) | VAF 7/193 reads (4%) | called by muse, mutect2
- RYR1 | c.18C>T p.G6= | Silent (SNP) | VAF 20/404 reads (5%) | called by muse, mutect2
- SARDH | c.888C>T p.V296= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as rs371310169; ClinVar: likely benign; called by muse, mutect2, varscan2
- SFT2D2 | c.48G>C p.R16= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- SHQ1 | c.1164G>C p.V388= | Silent (SNP) | VAF 10/352 reads (3%) | called by muse, mutect2
- SIGLEC7 | c.87G>A p.T29= | Silent (SNP) | VAF 34/220 reads (15%) | catalogued as rs1355670634, COSV58318151; called by muse, mutect2, varscan2
- SLAIN2 | c.213C>G p.L71= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- SLC9A5 | c.540C>T p.L180= | Silent (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2
- SRRD | c.738G>A p.G246= | Silent (SNP) | VAF 18/163 reads (11%) | catalogued as rs1021142162; called by muse, mutect2, varscan2
- SSH1 | c.1437C>T p.F479= | Silent (SNP) | VAF 28/422 reads (7%) | called by muse, mutect2
- TPD52L2 | c.198C>T p.V66= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as rs1405992795, COSV53861765; called by muse, mutect2, varscan2
- TRPA1 | c.3012C>T p.I1004= | Silent (SNP) | VAF 48/630 reads (8%) | catalogued as rs756362538; called by muse, mutect2
- TSR2 | c.180G>A p.L60= | Silent (SNP) | VAF 13/258 reads (5%) | called by muse, mutect2
- TTC6 | c.696C>T p.S232= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs1277906062, COSV101606811; called by muse, mutect2, varscan2
- UNC93B1 | c.1653C>T p.D551= | Silent (SNP) | VAF 23/186 reads (12%) | catalogued as COSV57100853; called by muse, mutect2, varscan2
- WFDC3 | c.468C>T p.R156= | Silent (SNP) | VAF 30/212 reads (14%) | called by muse, mutect2, varscan2
- ZBTB18 | c.795G>A p.L265= | Silent (SNP) | VAF 19/179 reads (11%) | called by muse, mutect2, varscan2
- ZNF334 | c.1596C>G p.L532= | Silent (SNP) | VAF 20/215 reads (9%) | catalogued as COSV100749026; called by muse, mutect2, varscan2
- ADAM11 | c.-5G>T | 5'UTR (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- ADAM1A | n.1842C>T | RNA (SNP) | VAF 38/412 reads (9%) | called by muse, mutect2
- ADAM1A | n.2071C>T | RNA (SNP) | VAF 24/262 reads (9%) | catalogued as rs915983481, COSV101437612; called by muse, mutect2
- APOL1 | c.188-1712G>C | Intron (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2
- BCAT1 | c.7-99G>C | Intron (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- CDC26 | c.-4C>G | 5'UTR (SNP) | VAF 32/258 reads (12%) | called by muse, mutect2, varscan2
- CELF4 | c.658-127C>T | Intron (SNP) | VAF 13/70 reads (19%) | catalogued as rs763166975; called by muse, mutect2, varscan2
- CLPX | c.-7C>T | 5'UTR (SNP) | VAF 15/106 reads (14%) | catalogued as COSV100269570; called by muse, mutect2, varscan2
- DLAT | c.*46C>T | 3'UTR (SNP) | VAF 45/274 reads (16%) | called by muse, mutect2, varscan2
- DNAJC19 | c.*725C>T | 3'UTR (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- ESPNP | n.1407G>A | RNA (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- FAM20A | c.*1716_*1741del | 3'UTR (DEL) | VAF 16/104 reads (15%) | called by mutect2, pindel
- GPATCH2L | c.1107+195G>A | Intron (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- ITGA4 | c.*1740C>G | 3'UTR (SNP) | VAF 28/252 reads (11%) | called by muse, mutect2, varscan2
- JAZF1-AS1 | n.1014G>A | RNA (SNP) | VAF 6/47 reads (13%) | catalogued as rs1299671084; called by mutect2, varscan2
- MON2 | chr12:62603220 A>G | 3'Flank (SNP) | VAF 3/48 reads (6%) | catalogued as rs1430530942; called by muse, mutect2
- MPDU1 | chr17:7583764 C>T | 5'Flank (SNP) | VAF 18/186 reads (10%) | catalogued as rs765346961; called by muse, varscan2
- NLRP3 | c.2150+12C>G | Intron (SNP) | VAF 14/234 reads (6%) | catalogued as COSV100275516, COSV100276429; called by muse, mutect2
- PLIN1 | c.*651C>A | 3'UTR (SNP) | VAF 17/225 reads (8%) | called by muse, mutect2
- POM121 | chr7:72948731 G>T | 3'Flank (SNP) | VAF 18/320 reads (6%) | catalogued as COSV57521202; called by muse, mutect2
- PTPN11 | c.-140G>A | 5'UTR (SNP) | VAF 11/204 reads (5%) | catalogued as rs1298197999; called by muse, mutect2
- RAB39B | c.-31C>T | 5'UTR (SNP) | VAF 19/211 reads (9%) | called by muse, mutect2
- RIPOR3 | chr20:50585834 G>T | 3'Flank (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- SCFD1 | c.312+859G>A | Intron (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- SETD9 | c.98+548A>G | Intron (SNP) | VAF 10/252 reads (4%) | called by muse, mutect2
- SLC25A18 | c.199+11C>T | Intron (SNP) | VAF 10/94 reads (11%) | catalogued as rs530751844; called by muse, mutect2
- SPG11 | c.6844-17C>T | Intron (SNP) | VAF 38/393 reads (10%) | called by muse, mutect2
- STK26 | c.-210C>G | 5'UTR (SNP) | VAF 36/308 reads (12%) | called by muse, mutect2, varscan2
- TMCO1 | c.*1603C>T | 3'UTR (SNP) | VAF 14/175 reads (8%) | catalogued as rs193179844; called by muse, mutect2
- TMCO1 | c.*892C>G | 3'UTR (SNP) | VAF 24/340 reads (7%) | called by muse, mutect2
- TOMM7 | c.*9T>G | 3'UTR (SNP) | VAF 34/252 reads (13%) | catalogued as COSV100627002; called by muse, mutect2, varscan2
- UBL5 | c.178+25G>A | Intron (SNP) | VAF 10/113 reads (9%) | catalogued as rs777296661; called by muse, mutect2, varscan2
- UPK2 | c.-45C>A | 5'UTR (SNP) | VAF 18/310 reads (6%) | called by muse, mutect2
- VGLL1 | c.688+86A>G | Intron (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- ZBBX | c.183-840C>T | Intron (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
